TCGA case TCGA-CV-7411 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Other and ill-defined sites in lip, oral cavity and pharynx; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/600fc87b-a177-4bf9-9084-457f7e7e102c

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Dead; Days to death: 2,717 days (7.4 years).

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C14.8; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 64.9 years (23,696 days); Year of diagnosis: 1994; AJCC staging edition: 7th; AJCC clinical T: T4a; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage IVA; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IVA; Tumor grade: G1; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Left.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 29; Margin status: Uninvolved.
   Pathology details: Lymph node dissection method: Functional (Limited) Neck Dissection; Lymph node dissection site: Neck, Right.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 2,717.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CV-7411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.4; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-CV-7411-01A-01-TS1: Section location: Top; Percent tumor cells: 86; Percent tumor nuclei: 71; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 14; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CV-7411-01A-01-BS1: Section location: Bottom; Percent tumor cells: 87; Percent tumor nuclei: 75; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 8; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 2.
- Sample TCGA-CV-7411-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CV-7411-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Anatomic organ subdivision: Oral Cavity; Lymph nodes examined: Yes; Lymph node neck dissection indicator: Yes; Margin status: Negative; Tobacco smoking history indicator: 2; Alcohol history documented: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,717 days; disease-specific survival: event status not recorded, 2,717 days; progression-free interval: no event (censored), 2,717 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CV-7411-01A-11D-2077-01): tumor purity 0.24, ploidy 4, whole-genome doublings 1.
